Somatic mutation profile of tumor specimen TCGA-IQ-A61E-01A (aliquot TCGA-IQ-A61E-01A-22D-A30E-08) from TCGA case TCGA-IQ-A61E, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.9 years (20,417 days).
Specimen TCGA-IQ-A61E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecab3b73-3787-4d4f-8153-c88e33689367.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61E-10A (Blood Derived Normal), aliquot TCGA-IQ-A61E-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd373939-df8e-40a0-8e4d-b3cec4c3682c

The open-access MAF lists 183 somatic variants for this specimen: 129 protein-altering or splice-affecting, 51 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 51, Nonsense Mutation 16, Splice Site 3, Frame Shift Del 2, Splice Region 2, 5'UTR 1, In Frame Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN1 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV99517334; called by muse, mutect2
- AGGF1 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs1266888554, COSV100461534; called by muse, mutect2, varscan2
- AKAP4 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV62073944, COSV62074900; called by muse, mutect2, varscan2
- AKIP1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1264462075, COSV100214865; called by muse, mutect2
- ALK | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.297); catalogued as rs1035402110, COSV66564819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30A | c.1893C>G p.F631L (on ENST00000611781; = p.F575L on NM_052997.2) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100652987; called by muse, mutect2
- ARVCF | c.1906A>G p.M636V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99598956; called by muse, mutect2, varscan2
- ASTE1 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV99393641, COSV99393642; called by muse, mutect2, varscan2
- ATMIN | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100214522; called by muse, mutect2
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMSAP2 | c.965A>C p.N322T (on ENST00000236925 / NM_001297707.2; = p.N311T on NM_203459.3) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99372908; called by muse, mutect2, varscan2
- CD96 | c.856-1G>C p.X286_splice (on ENST00000283285 / NM_198196.3; = p.X270_splice on NM_005816.5) | Splice Site (SNP) | VAF 52/129 reads (40%) | catalogued as rs750921261, COSV99342401; called by muse, mutect2, varscan2
- CDH3 | c.2433G>C p.E811D | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.191); catalogued as COSV99867618; called by muse, mutect2, varscan2
- CNKSR1 | c.1411C>T p.Q471* (on ENST00000374253 / NM_001297647.2; = p.Q464* on NM_006314.3) | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | catalogued as COSV100128224; called by muse, mutect2, varscan2
- CNTROB | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as COSV100972604; called by muse, mutect2, varscan2
- CNTROB | c.1167G>A p.E389= | Splice Region (SNP) | VAF 29/146 reads (20%) | catalogued as COSV100972605; called by muse, mutect2, varscan2
- COL11A1 | c.2278G>A p.G760S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100615297; called by muse, mutect2, varscan2
- COL18A1 | c.1820C>G p.S607* (on ENST00000359759 / NM_130444.3; = p.S372* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100700475; called by muse, mutect2, varscan2
- CWF19L1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as rs557407789, COSV100821456; called by muse, mutect2
- DCP2 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV101203847; called by muse, mutect2, varscan2
- DNAH3 | c.1564A>C p.N522H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV99765185; called by muse, mutect2, varscan2
- DNAH5 | c.12430C>T p.Q4144* | Nonsense Mutation (SNP) | VAF 45/138 reads (33%) | catalogued as rs767823262, COSV99445529; called by muse, mutect2
- EIF2B5 | c.1009G>A p.D337N (on ENST00000647909; = p.D329N on NM_003907.3) | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99889018; called by muse, mutect2, varscan2
- ELP1 | c.2829T>A p.Y943* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV101010347; called by muse, mutect2, varscan2
- EPDR1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV99554266; called by muse, mutect2
- EPHA2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs745943908, COSV64452687, COSV64453095; called by muse, mutect2, varscan2
- EPHA7 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100993300; called by muse, mutect2, varscan2
- ESF1 | c.1155T>A p.Y385* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99176276; called by muse, varscan2
- FAM217A | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV99212680; called by muse, mutect2
- FBLL1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100606135; called by muse, mutect2, varscan2
- FIBCD1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs1188538633, COSV99446779, COSV99447277; called by muse, mutect2, varscan2
- FPR1 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.216); catalogued as COSV100493941; called by muse, mutect2, varscan2
- GLUD2 | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 31/132 reads (23%) | catalogued as COSV100046631; called by muse, mutect2, varscan2
- GPATCH1 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV99403775; called by muse, mutect2
- GPT | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146211713; called by muse, mutect2, varscan2
- GRP | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV99900890; called by muse, mutect2, varscan2
- GSPT2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100467934; called by muse, mutect2, varscan2
- H2AC17 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 16/312 reads (5%) | catalogued as COSV100377483; called by muse, mutect2
- HDX | c.479C>A p.A160E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV99946691; called by muse, varscan2
- HSPA5 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV100189796; called by muse, mutect2, varscan2
- HYOU1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101345545, COSV101345709; called by muse, mutect2, varscan2
- KCNH7 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV59785526; called by muse, mutect2, varscan2
- KCNJ15 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV100154034; called by muse, mutect2, varscan2
- KIF16B | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100733826; called by muse, mutect2, varscan2
- KIF20B | c.5378G>A p.G1793D (on ENST00000371728 / NM_001284259.2; = p.G1753D on NM_016195.4) | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99589539; called by muse, mutect2, varscan2
- KIF3B | c.1892C>G p.S631* | Nonsense Mutation (SNP) | VAF 12/128 reads (9%) | catalogued as COSV100996325; called by muse, mutect2
- KIFC2 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.204); catalogued as COSV100023554; called by muse, mutect2, varscan2
- KLF17 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs144146386; called by muse, mutect2, varscan2
- KLHL40 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs1238979900, COSV99825349; called by muse, mutect2, varscan2
- KPNA4 | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100515020; called by muse, mutect2, varscan2
- KRT24 | c.1248G>C p.Q416H | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99231927; called by muse, mutect2, varscan2
- LEFTY1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs376691125; called by muse, mutect2, varscan2
- LRRC74A | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs200189415, COSV99372215; called by muse, mutect2, varscan2
- MADD | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 37/328 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV100211085; called by muse, mutect2, varscan2
- MAGEC1 | c.2595C>G p.S865R | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV53580834, COSV99594929; called by muse, mutect2
- MARCHF10 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV100247849; called by muse, mutect2, varscan2
- MED14 | c.2924G>A p.R975K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as COSV100247325; called by muse, mutect2, varscan2
- MEN1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53641771, COSV99580439; called by muse, mutect2, varscan2
- MICAL2 | c.3823C>T p.L1275F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); catalogued as COSV99811451; called by muse, mutect2, varscan2
- MSH5 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100991754; called by muse, mutect2, varscan2
- MTHFD1L | c.2220A>T p.L740F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100944880; called by muse, mutect2, varscan2
- MUC16 | c.11554A>G p.R3852G | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV101198334; called by muse, mutect2, varscan2
- MXRA5 | c.3125A>G p.H1042R | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99475920; called by muse, mutect2, varscan2
- MYO9B | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as COSV101261313; called by muse, mutect2, varscan2
- MYSM1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs770747091, COSV68977398; called by muse, mutect2
- NBEAL1 | c.5161A>T p.M1721L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101495612; called by muse, mutect2, varscan2
- NIN | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV99811837; called by muse, mutect2, varscan2
- NPY1R | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1169351878, COSV56716347; called by muse, mutect2, varscan2
- OPRL1 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100401954; called by muse, mutect2, varscan2
- OR51S1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV59057812; called by muse, mutect2
- OR5A2 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV100119676; called by muse, mutect2, varscan2
- OR8D4 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as COSV100361711; called by muse, mutect2, varscan2
- ORC3 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs764172750, COSV57641374; called by muse, mutect2, varscan2
- OSBPL9 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100542991; called by muse, mutect2, varscan2
- OTOF | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs562267762, COSV55503188; called by muse, mutect2, varscan2
- PAK1IP1 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV101093338; called by muse, mutect2, varscan2
- PARP2 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51639040; called by muse, mutect2
- PCYOX1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756161282, COSV52476531; called by muse, mutect2, varscan2
- PGM1 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100936524; called by muse, mutect2, varscan2
- PIH1D2 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99735265; called by muse, mutect2, varscan2
- PLEC | c.7855G>A p.E2619K (on ENST00000322810 / NM_201380.4; = p.E2509K on NM_000445.5) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as COSV100511273, COSV59697468; called by muse, mutect2, varscan2
- PLPPR4 | c.1411C>T p.Q471* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | catalogued as COSV100926706; called by muse, mutect2, varscan2
- PLS3 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99171609; called by muse, mutect2
- PPP2R1B | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100231892; called by muse, mutect2, varscan2
- PRUNE2 | c.342G>A p.A114= | Splice Region (SNP) | VAF 6/71 reads (8%) | catalogued as rs1003543054, COSV100942816; called by muse, mutect2
- PSG11 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 87/356 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100105505; called by muse, mutect2, varscan2
- PYGL | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as COSV99368281; called by muse, mutect2, varscan2
- PYGL | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV53586338; called by muse, mutect2, varscan2
- RBM25 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV99998444; called by muse, mutect2, varscan2
- RBM47 | c.1639C>T p.P547S (on ENST00000295971 / NM_001098634.2; = p.P478S on NM_019027.4) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV99920174; called by muse, mutect2, varscan2
- RGS5 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV100008863; called by muse, mutect2
- RIPOR3 | c.2459C>T p.T820I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs762392679, COSV50389189; called by muse, mutect2, varscan2
- RLF | c.3377C>T p.P1126L | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV101035104; called by muse, mutect2, varscan2
- RNF213 | c.9079C>T p.Q3027* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | catalogued as COSV100299784; called by muse, mutect2
- SCARB2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99357808; called by muse, mutect2, varscan2
- SERPINA1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs749021630, COSV100871998; called by muse, mutect2, varscan2
- SETD6 | c.1185G>T p.R395S (on ENST00000219315 / NM_001160305.4; = p.R371S on NM_024860.3) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99543031; called by muse, mutect2, varscan2
- SIK2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs749241959, COSV59252079; called by muse, mutect2, varscan2
- SIN3A | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845046; called by muse, mutect2, varscan2
- SLC34A2 | c.1507T>C p.Y503H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101158229; called by muse, mutect2
- SMG8 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99958696; called by muse, mutect2, varscan2
- SP100 | c.2106G>C p.K702N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV99892374; called by muse, mutect2, varscan2
- TEAD1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100531765; called by muse, mutect2, varscan2
- TEX47 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV51878925, COSV51879134; called by muse, mutect2
- TNFRSF21 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs148136049; called by muse, mutect2, varscan2
- TP53 | c.1101-2A>T p.X367_splice | Splice Site (SNP) | VAF 54/112 reads (48%) | catalogued as CS111031, COSV52676811, COSV52714663, COSV53348267; called by muse, mutect2, varscan2
- TSGA10 | c.1504G>C p.V502L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.76); catalogued as COSV100747446; called by muse, mutect2, varscan2
- UBL7 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV100795351; called by muse, mutect2, varscan2
- UBR2 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100868436; called by muse, mutect2, varscan2
- UGP2 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100451513; called by muse, mutect2, varscan2
- USP51 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV101540645; called by muse, mutect2, varscan2
- UTP14C | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101584247, COSV73000613; called by muse, mutect2, varscan2
- UTRN | c.10033C>A p.Q3345K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100838186, COSV62309436; called by muse, varscan2
- VPS13D | c.12692G>A p.R4231H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895472739, COSV50670974, COSV50694804; called by muse, mutect2, varscan2
- XKR4 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100531009, COSV100534206; called by muse, mutect2, varscan2
- ZBTB38 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100375376; called by muse, mutect2, varscan2
- ZNF624 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100257028; called by muse, mutect2, varscan2
- ZSCAN29 | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV101212178; called by muse, mutect2, varscan2
- BRD4 | c.3748_3750del p.K1250del | In Frame Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- FAT1 | c.7314_7320del p.F2438Lfs*18 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3371_3384del p.D1124Afs*15 | Frame Shift Del (DEL) | VAF 25/58 reads (43%) | called by pindel, varscan2
- PRAMEF15 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A1 | c.4041C>G p.I1347M | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- TRBV19 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- WASHC2C | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ZNF488 | c.623C>A p.S208* | Nonsense Mutation (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- ZNF488 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ABCA4 | c.4137C>G p.L1379= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100933032, COSV64671769; called by mutect2, varscan2
- ADAMTS12 | c.1815G>A p.Q605= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs1255409579, COSV100710329, COSV61262958; called by muse, mutect2
- ALDH1L1 | c.2586G>A p.T862= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as rs767390342, COSV56415232, COSV99856534; called by muse, mutect2
- CASR | c.153C>G p.L51= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs779428235, COSV99948502; called by muse, mutect2, varscan2
- CD22 | c.1962G>A p.S654= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs759584926; called by muse, mutect2, varscan2
- CDK5 | c.573C>T p.I191= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99876675; called by muse, mutect2, varscan2
- CGAS | c.580C>T p.L194= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100943624; called by muse, mutect2, varscan2
- CIZ1 | c.1116G>A p.Q372= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV99476673; called by muse, mutect2, varscan2
- CPNE3 | c.585G>A p.K195= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV99547192; called by muse, mutect2
- CUL7 | c.4494C>G p.L1498= | Silent (SNP) | VAF 13/168 reads (8%) | catalogued as COSV99537979; called by muse, mutect2
- CYP1A2 | c.660G>A p.V220= | Silent (SNP) | VAF 65/236 reads (28%) | catalogued as rs774038132, COSV100673859; called by muse, mutect2, varscan2
- ERBIN | c.2337G>A p.E779= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99395940; called by muse, mutect2, varscan2
- FBXO7 | c.741C>T p.S247= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs1190620521; called by muse, mutect2, varscan2
- FLG | c.7902C>T p.S2634= | Silent (SNP) | VAF 58/416 reads (14%) | catalogued as COSV100910579; called by muse, mutect2, varscan2
- GLP2R | c.1107C>T p.L369= | Silent (SNP) | VAF 10/213 reads (5%) | catalogued as COSV99301426, COSV99301631; called by muse, mutect2
- GPR119 | c.114T>C p.G38= | Silent (SNP) | VAF 123/433 reads (28%) | catalogued as COSV99358537; called by muse, mutect2, varscan2
- GRIA3 | c.2415C>T p.C805= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV52052447; called by muse, mutect2, varscan2
- GSTK1 | c.429G>A p.E143= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as rs949208708, COSV100621739; called by muse, mutect2, varscan2
- HGFAC | c.774G>C p.L258= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100122601, COSV58757699; called by muse, mutect2, varscan2
- HTR1A | c.66C>T p.G22= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs200335552, COSV60501130, COSV60501259; called by muse, mutect2, varscan2
- ITGB1BP2 | c.843C>G p.V281= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV99338599; called by muse, mutect2, varscan2
- KLHL6 | c.1116C>T p.C372= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs149326068; called by muse, mutect2, varscan2
- KRT80 | c.1332C>T p.F444= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100502507; called by muse, mutect2, varscan2
- LNPEP | c.951C>A p.I317= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1415007797, COSV99183479; called by muse, mutect2, varscan2
- MAML2 | c.2544C>T p.L848= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- MELTF | c.1485G>A p.Q495= | Silent (SNP) | VAF 12/171 reads (7%) | catalogued as COSV99585865; called by muse, mutect2
- MFNG | c.660C>T p.F220= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100812855, COSV63690644; called by muse, mutect2
- MYH1 | c.4719G>A p.K1573= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV99875002; called by muse, mutect2, varscan2
- MYH9 | c.1668C>T p.F556= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV99337938; called by muse, mutect2, varscan2
- NLGN1 | c.1353C>A p.T451= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV100848780; called by muse, mutect2, varscan2
- NUP85 | c.903G>A p.L301= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV99822981; called by muse, mutect2, varscan2
- PCDH11X | c.3472C>T p.L1158= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100008620; called by muse, mutect2, varscan2
- PCDHB6 | c.1371C>T p.F457= | Silent (SNP) | VAF 30/353 reads (8%) | catalogued as rs782069574, COSV50697736; called by muse, mutect2
- PIGL | c.111G>A p.L37= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99247719; called by muse, mutect2, varscan2
- PLEC | c.6453G>C p.L2151= (on ENST00000322810 / NM_201380.4; = p.L2041= on NM_000445.5) | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- POLR3A | c.858C>T p.I286= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs912248653, COSV100965545; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1587C>T p.F529= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as rs1289555679, COSV99460866; called by muse, mutect2
- PYGL | c.1113G>A p.K371= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV99368283; called by muse, mutect2, varscan2
- RANBP17 | c.2988G>A p.R996= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV101206096; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.27G>A p.E9= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV59086937, COSV59087798; called by muse, mutect2, varscan2
- SLC20A1 | c.57G>A p.V19= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99733889; called by muse, mutect2, varscan2
- SLC6A17 | c.1458C>T p.I486= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs1310962386, COSV58991291, COSV58994893; called by muse, mutect2, varscan2
- SP100 | c.2475G>C p.L825= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99892377; called by muse, mutect2, varscan2
- TMEM132D | c.115A>C p.R39= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101396554, COSV70594836; called by muse, mutect2, varscan2
- TOM1L2 | c.1329G>A p.R443= (on ENST00000379504 / NM_001350333.2; = p.R393= on NM_001033551.3) | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV100540890; called by muse, mutect2, varscan2
- TRIM54 | c.525C>T p.S175= (on ENST00000380075 / NM_187841.3; = p.S217= on NM_032546.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs772077566, COSV99274184; called by muse, varscan2
- TTC16 | c.1944G>A p.S648= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs745706393, COSV100262696; called by muse, mutect2, varscan2
- TYK2 | c.573C>G p.L191= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV53388350; called by muse, mutect2, varscan2
- UBR1 | c.1125C>T p.F375= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV51931273; called by muse, mutect2, varscan2
- VPS13D | c.1878C>G p.L626= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as COSV100692620; called by muse, mutect2
- WLS | c.621G>A p.K207= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as COSV52039666, COSV99258758; called by muse, mutect2, varscan2
- DLG3 | c.1145+722G>C | Intron (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99529213; called by muse, mutect2
- FPR1 | c.*2G>T | 3'UTR (SNP) | VAF 46/160 reads (29%) | catalogued as COSV100493940; called by muse, mutect2, varscan2
- VPS11 | c.-832C>T | 5'UTR (SNP) | VAF 14/108 reads (13%) | catalogued as rs536672392, COSV56184264; called by muse, mutect2, varscan2
